Somatic mutation profile of tumor specimen MP2PRT-PAVVMN-TMP1-A (aliquot MP2PRT-PAVVMN-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVVMN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,125 days).
Specimen MP2PRT-PAVVMN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cda91955-7836-453e-b398-14de84a067e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVVMN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVVMN-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2035bbaf-5ca1-49c0-bb76-c99107d4f705

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GAS2L2 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 47/503 reads (9%) | catalogued as rs782521632; called by muse, mutect2
- SALL3 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 257/655 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs759085561, COSV73305862; called by muse, mutect2, varscan2
- CSKMT | c.256A>T p.T86S | Missense Mutation (SNP) | VAF 227/493 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- KMT2D | c.11665_11666insGCCCC p.L3889Rfs*3 | Frame Shift Ins (INS) | VAF 108/428 reads (25%) | called by pindel, varscan2
- LGI2 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 127/356 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MGAT4C | c.433A>T p.N145Y | Missense Mutation (SNP) | VAF 110/367 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- NUP210L | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 163/371 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53 | c.454_468del p.P152_R156del | In Frame Del (DEL) | VAF 79/397 reads (20%) | called by mutect2, pindel, varscan2
